Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PU-01A from TCGA case TCGA-VQ-A8PU, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 72.9 years (26,625 days).
Specimen TCGA-VQ-A8PU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.3252b2ee-83e8-4509-8903-8bccde31b0bb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PU-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/90afb8ad-fb78-437f-8fba-7e36b2b7d71b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 2: 11,967; copy number 3: 13,339; copy number 4: 19,731; copy number 5: 9,563; copy number 6: 3,169; copy number 7: 625; copy number 8: 34; copy number 9: 952; copy number 10: 314; copy number 11: 53; copy number 14: 12; copy number 19: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PU-01A-12D-A40Z-01): tumor purity 0.66, ploidy 3.84, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,994,139–24,592,104, 25 genes: CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,358 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,271,566–56,954,649, 337 genes, copy number 9–10 (broad region; genes not listed).
- chr6:61,240,898–62,611,327, 8 genes, copy number 9: AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr6:67,456,346–68,329,899, 12 genes, copy number 14 (within-gene range 2–14): AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549.
- chr7:67,627,831–67,697,029, 3 genes, copy number 11: MTATP6P21, MTCO3P41, AC005482.1.
- chr7:72,829,425–75,789,896, 110 genes, copy number 9 (broad region; genes not listed).
- chr11:67,483,026–68,844,410, 55 genes, copy number 9 (within-gene range 6–9): AIP, MIR6752, PITPNM1, CDK2AP2, CABP2, AP001184.1, GSTP1, C11orf72, AP003385.3, NDUFV1, DOC2GP, NUDT8, TBX10, ACY3, AP003385.1, ALDH3B2, RPL37P2, UNC93B5, OR7E145P, OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P, ENPP7P7, AP003716.1, LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P, UNC93B1, ALDH3B1, AC004923.4, NDUFS8, MIR7113, MIR4691, TCIRG1, MIR6753, AP002807.1, CHKA, AP002992.1, KMT5B, C11orf24, AP002813.1, LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A.
- chr11:69,641,156–72,080,693, 78 genes, copy number 11–19 (within-gene range 2–19) (broad region; genes not listed).
- chr15:87,325,829–101,933,350, 351 genes, copy number 9–10 (broad region; genes not listed).
- chr20:47,501,887–64,313,132, 404 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
